Somatic mutation profile of tumor specimen TCGA-ZF-A9RL-01A (aliquot TCGA-ZF-A9RL-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9RL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 61.5 years (22,480 days).
Specimen TCGA-ZF-A9RL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 511bb983-7a62-4989-9521-bb0ab5868870.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9RL-10A (Blood Derived Normal), aliquot TCGA-ZF-A9RL-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99cdcc72-e027-44b0-8128-79e2b9f6836d

The open-access MAF lists 352 somatic variants for this specimen: 276 protein-altering or splice-affecting, 69 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 234, Silent 69, Nonsense Mutation 27, Splice Site 8, RNA 3, Nonstop Mutation 2, Intron 2, Frame Shift Ins 2, Splice Region 1, 3'UTR 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*1004A>G | 3'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as rs78311289, CM002967, CM950476, COSV53390625, COSV53407424; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1531-1G>C p.X511_splice | Splice Site (SNP) | VAF 7/70 reads (10%) | hotspot (GDC flag); catalogued as COSV59536648, COSV59540425, COSV59548961; called by muse, mutect2, varscan2
- HNF4A | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1555813319, CM111488, COSV57385421; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- PIK3CA | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 31/61 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.177); catalogued as rs200018596, CM1312620, COSV55890007, COSV55898949, COSV55991501; called by muse, mutect2, varscan2
- AADACL2 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.162); catalogued as COSV62931181; called by muse, mutect2
- AASS | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62790741; called by muse, mutect2, varscan2
- ABCA1 | c.1920G>T p.M640I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV66067943; called by muse, mutect2, varscan2
- ABCE1 | c.539C>A p.A180E | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV56847771; called by muse, mutect2, varscan2
- ABLIM2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV56404755; called by muse, mutect2, varscan2
- AC090517.4 | c.1845G>T p.E615D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50998289; called by muse, mutect2
- ACTN3 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.737); catalogued as COSV72207630; called by muse, mutect2, varscan2
- ACTN3 | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV59749499; called by muse, mutect2, varscan2
- ADAM29 | c.2332C>T p.Q778* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | catalogued as rs1373234980, COSV100822309; called by muse, varscan2
- ADGRV1 | c.1801G>C p.D601H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67989286, COSV67994803; called by muse, mutect2, varscan2
- ADRA2A | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54527171; called by muse, mutect2, varscan2
- AFF1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV57121535; called by muse, mutect2
- AFG3L2 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs765789778, COSV52315703; called by muse, mutect2, varscan2
- AFM | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56920945; called by muse, mutect2, varscan2
- ALDH3B2 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100824165, COSV62427985; called by muse, mutect2
- AMER3 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58465992; called by muse, mutect2, varscan2
- AMMECR1L | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as rs751024861, COSV55761257; called by muse, mutect2, varscan2
- ANAPC1 | c.4639G>A p.G1547S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV100595198; called by mutect2, varscan2
- ANK3 | c.12016G>C p.E4006Q | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55066700; called by muse, mutect2, varscan2
- ANK3 | c.7063G>A p.E2355K | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV55052546; called by muse, mutect2, varscan2
- AP2A2 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1564809876, COSV100173443; called by muse, mutect2
- AP3B1 | c.3020C>G p.S1007C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV54887177; called by muse, mutect2, varscan2
- AP4E1 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55918254, COSV55919997; called by muse, mutect2, varscan2
- ARIH2 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.339); catalogued as rs1188970482, COSV62705342; called by muse, mutect2, varscan2
- ASB12 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV62856425; called by muse, mutect2, varscan2
- ASB2 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV100279542, COSV100279677; called by muse, mutect2
- ASMTL | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV67244276; called by muse, mutect2, varscan2
- ASXL2 | c.1653G>A p.M551I | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV55461938; called by muse, mutect2, varscan2
- ATAD2B | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99478712; called by muse, mutect2
- ATG2B | c.4682G>C p.G1561A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55891221; called by muse, mutect2, varscan2
- ATP6V1B2 | c.604-1G>A p.X202_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99369640; called by muse, mutect2
- ATR | c.3542G>T p.G1181V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV63393449; called by muse, mutect2
- BIRC6 | c.1894C>T p.L632F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70202173; called by muse, mutect2, varscan2
- BLNK | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs781998086, COSV56412272; called by muse, mutect2, varscan2
- BSN | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs1375390739, COSV99610172; called by muse, mutect2
- BTBD3 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54779174; called by muse, mutect2, varscan2
- BTG1 | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55459481; called by muse, mutect2, varscan2
- C19orf53 | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV99237931; called by muse, mutect2
- C1orf131 | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.337); catalogued as COSV59642622; called by muse, mutect2, varscan2
- C2CD2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as COSV61599961; called by muse, mutect2, varscan2
- CAMLG | c.36G>C p.E12D | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51805128; called by muse, mutect2, varscan2
- CARMIL1 | c.2248G>T p.G750C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1268680477, COSV61520043; called by muse, mutect2, varscan2
- CARMIL1 | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.594); catalogued as rs781053870, COSV61517630, COSV61520051; called by muse, mutect2, varscan2
- CCDC130 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs750897903, COSV55583881, COSV99075709; called by muse, mutect2, varscan2
- CD27 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV56947598; called by muse, mutect2, varscan2
- CEMP1 | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV53551397; called by muse, mutect2, varscan2
- CHKA | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV55839699; called by muse, mutect2, varscan2
- CHODL | c.634+1G>A p.X212_splice | Splice Site (SNP) | VAF 26/83 reads (31%) | catalogued as rs1265805302, COSV54733584; called by muse, mutect2, varscan2
- CHRNA7 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV60972421; called by muse, mutect2, varscan2
- CILK1 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV63154988; called by muse, mutect2, varscan2
- CIT | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV55874131; called by muse, mutect2, varscan2
- CLASP1 | c.89A>G p.Y30C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs189760808, COSV55329368; called by muse, mutect2, varscan2
- CLYBL | c.447C>G p.D149E | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100185836; called by muse, mutect2
- CNKSR1 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs746860230, COSV64163634; called by muse, mutect2, varscan2
- CNKSR3 | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV70481284; called by muse, mutect2, varscan2
- CNOT1 | c.5011_5016del p.D1671_A1672del | In Frame Del (DEL) | VAF 24/51 reads (47%) | catalogued as COSV55319015; called by mutect2, pindel, varscan2
- CNTN6 | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV63178465; called by muse, mutect2, varscan2
- CNTN6 | c.3016G>C p.E1006Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV63178470; called by muse, mutect2, varscan2
- COBLL1 | c.1757T>C p.L586S (on ENST00000392717; = p.L548S on NM_014900.5) | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV52070982; called by muse, mutect2, varscan2
- COG1 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV55430630; called by muse, mutect2, varscan2
- COL14A1 | c.4315-1G>T p.X1439_splice | Splice Site (SNP) | VAF 41/329 reads (12%) | catalogued as COSV52859741; called by muse, mutect2, varscan2
- CPSF3 | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53010486; called by muse, mutect2, varscan2
- CREBBP | c.7142G>T p.G2381V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV52129995; called by muse, mutect2, varscan2
- CREBBP | c.7141G>T p.G2381C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV52130011; called by muse, mutect2, varscan2
- CUL1 | c.161C>G p.T54S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV57390041; called by muse, mutect2, varscan2
- CYFIP2 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs1462491993, COSV100558012; called by muse, mutect2, varscan2
- CYP24A1 | c.856A>C p.I286L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV53775338; called by muse, mutect2, varscan2
- DBF4 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs1362333859, COSV55997714; called by muse, mutect2, varscan2
- DHX34 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV60896148; called by muse, mutect2, varscan2
- DNAH5 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763771549, COSV54216174; called by muse, mutect2, varscan2
- DNAJC16 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.796); catalogued as COSV65448973; called by muse, mutect2, varscan2
- DNMT1 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.946); catalogued as COSV61580886; called by muse, varscan2
- DNMT1 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61580895; called by muse, mutect2, varscan2
- DOP1B | c.1851G>A p.W617* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV101215926; called by muse, mutect2, varscan2
- DSE | c.293G>C p.W98S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100528736, COSV59065296; called by muse, mutect2, varscan2
- DSE | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59065311; called by muse, mutect2, varscan2
- DSP | c.5419C>G p.Q1807E | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as CM156308, COSV65792219, COSV65793814; called by muse, mutect2
- DST | c.15469C>T p.Q5157* (on ENST00000361203 / NM_001374722.1; = p.Q2745* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV99761078; called by muse, mutect2, varscan2
- EDNRA | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); catalogued as rs202191899, COSV60099121; called by muse, mutect2, varscan2
- EED | c.1322G>C p.R441P | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54554550, COSV54556640; called by muse, mutect2, varscan2
- EFNA1 | c.506A>G p.D169G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as COSV57597328; called by muse, mutect2, varscan2
- ENKD1 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54668742; called by muse, mutect2, varscan2
- EPB41L5 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55354334; called by muse, mutect2, varscan2
- EPHA8 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs202015824, COSV51267123; called by muse, mutect2, varscan2
- EPS8L1 | c.209G>C p.R70P | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52383669, COSV52385076, COSV52385224; called by muse, mutect2, varscan2
- EWSR1 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as rs759221648, COSV58425288; called by muse, mutect2, varscan2
- EXOC6B | c.1551A>G p.L517= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99726947; called by mutect2, varscan2
- EYS | c.411T>A p.N137K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.614); catalogued as COSV60991608; called by muse, mutect2, varscan2
- FAT1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1464063308, COSV71674917; called by muse, mutect2, varscan2
- FBXL19 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs746760154, COSV57943434; called by muse, mutect2, varscan2
- FBXO44 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 5/91 reads (5%) | catalogued as COSV99279156; called by muse, mutect2
- FBXO5 | c.1256G>C p.C419S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57671178; called by muse, mutect2, varscan2
- FER | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55296236; called by muse, mutect2, varscan2
- FILIP1L | c.1678G>C p.V560L (on ENST00000354552 / NM_182909.3; = p.V320L on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58767363, COSV58771709; called by muse, mutect2, varscan2
- FNBP4 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as COSV55450028; called by muse, mutect2, varscan2
- FOLR3 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV61530553; called by muse, mutect2, varscan2
- FOXRED1 | c.1362G>C p.E454D | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV99703200; called by muse, mutect2
- FRY | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100970045; called by muse, mutect2, varscan2
- FSD2 | c.1209G>C p.E403D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.831); catalogued as COSV58011087; called by muse, mutect2, varscan2
- FUBP3 | c.1131C>G p.I377M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60515036; called by muse, mutect2, varscan2
- GABRA2 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV62915682, COSV62916534, COSV62918977; called by muse, mutect2, varscan2
- GCLC | c.914C>T p.S305F (on ENST00000643939; = p.S303F on NM_001498.4) | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57593603, COSV57596380; called by muse, mutect2, varscan2
- GRIK2 | c.1607T>A p.L536H | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59749211; called by muse, varscan2
- GRIP2 | c.2114C>G p.A705G (on ENST00000619221; = p.A608G on NM_001080423.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766543232, COSV56122700; called by mutect2, varscan2
- GRK2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV57950181; called by muse, mutect2, varscan2
- GTF3C1 | c.1243G>T p.G415* | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100649827; called by muse, mutect2
- GTF3C1 | c.1243-1G>T p.X415_splice | Splice Site (SNP) | VAF 10/110 reads (9%) | catalogued as COSV62242538; called by muse, mutect2
- GTF3C2 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV53127581; called by muse, mutect2, varscan2
- GTF3C3 | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as COSV99826965; called by muse, mutect2, varscan2
- H3C8 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as rs1453083205, COSV59953274; called by muse, mutect2, varscan2
- HACL1 | c.869G>C p.G290A | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58255203; called by muse, mutect2, varscan2
- HIVEP2 | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV50022675; called by muse, mutect2, varscan2
- HIVEP2 | c.2103G>C p.K701N | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV50022775; called by muse, mutect2, varscan2
- HIVEP2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV50022900; called by muse, varscan2
- HOXC13 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as COSV54499297; called by muse, mutect2, varscan2
- HSPG2 | c.7390G>T p.A2464S | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV65973735; called by muse, mutect2
- HSPG2 | c.4363G>A p.E1455K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs750944653, COSV65973738; called by muse, mutect2, varscan2
- HUWE1 | c.6004G>A p.D2002N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.107); catalogued as COSV53353236; called by muse, mutect2, varscan2
- IFNGR1 | c.532A>G p.M178V | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV62990044; called by muse, mutect2, varscan2
- IL3RA | c.817A>G p.R273G | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV58432156; called by muse, mutect2, varscan2
- IQGAP1 | c.2680G>T p.E894* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99185487; called by muse, mutect2, varscan2
- IRAK1 | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV100318590; called by muse, mutect2
- IVNS1ABP | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV62251481; called by muse, mutect2, varscan2
- KANSL1 | c.2467G>T p.V823L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.511); catalogued as COSV52270630; called by muse, mutect2, varscan2
- KHDRBS2 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1408764252, COSV55468978; called by muse, mutect2, varscan2
- KIF1B | c.3291G>C p.K1097N (on ENST00000377086 / NM_001365952.1; = p.K1051N on NM_015074.3) | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV55811274; called by muse, mutect2, varscan2
- KLHDC10 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100111073; called by muse, mutect2, varscan2
- KNDC1 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as COSV58843764; called by muse, mutect2, varscan2
- LARP1 | c.1693C>T p.R565W (on ENST00000518297 / NM_033551.3; = p.R488W on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1481696091, COSV60428717; called by muse, mutect2, varscan2
- LIPJ | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV64245794; called by muse, mutect2, varscan2
- LRRC36 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV52078188, COSV52080538; called by muse, mutect2
- LRRN1 | c.1650G>C p.M550I | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV60014754; called by muse, mutect2, varscan2
- MAPK14 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57696535; called by muse, mutect2, varscan2
- MARCHF7 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52029615, COSV99373518; called by muse, mutect2
- MDC1 | c.2623G>C p.D875H | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV64525317; called by muse, mutect2, varscan2
- MDGA2 | c.2178G>C p.W726C (on ENST00000399232 / NM_001113498.2; = p.W428C on NM_182830.4) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62100834; called by muse, mutect2, varscan2
- MED13 | c.1668G>C p.Q556H | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV67264973; called by muse, mutect2, varscan2
- MET | c.4169C>G p.S1390* | Nonsense Mutation (SNP) | VAF 43/137 reads (31%) | catalogued as COSV100577521, COSV59265676; called by muse, mutect2, varscan2
- METTL17 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs758787257, COSV59555769, COSV59556411; called by muse, mutect2, varscan2
- MXRA8 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs942011440, COSV58510966, COSV58511048; called by muse, mutect2, varscan2
- MYH11 | c.3648G>C p.K1216N | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV55559146; called by muse, mutect2, varscan2
- MYH13 | c.3501G>T p.M1167I | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV52834204, COSV52837535; called by muse, mutect2, varscan2
- MYH14 | c.4271G>T p.R1424L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV51811684, COSV51823337; called by muse, mutect2, varscan2
- MYLIP | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.567); catalogued as rs752488097, COSV62767092; called by muse, mutect2, varscan2
- MYNN | c.963G>T p.M321I | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.824); catalogued as rs1363278410, COSV100582373; called by muse, mutect2
- MYOM1 | c.5005G>A p.E1669K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.293); catalogued as COSV55302172; called by muse, mutect2
- NAV3 | c.4933C>A p.Q1645K | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV57092686; called by muse, mutect2
- NDUFB10 | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51910442; called by muse, mutect2, varscan2
- NEK1 | c.3193G>T p.D1065Y | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101455928; called by muse, mutect2
- NEPRO | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1445412545, COSV58723822; called by muse, mutect2, varscan2
- NEUROD1 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs759568651, COSV54550062; called by muse, mutect2, varscan2
- NOB1 | c.676G>C p.V226L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99264134; called by muse, mutect2
- NPC1 | c.2663C>G p.P888R | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52577591, COSV52580697; called by muse, mutect2, varscan2
- NPHP3 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV58129604, COSV58129804; called by muse, mutect2, varscan2
- NRAS | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.471); catalogued as rs776195467, COSV65742813; called by muse, mutect2, varscan2
- NRBP1 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV51994960; called by muse, mutect2, varscan2
- NUDT19 | c.571A>G p.I191V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs755035452, COSV101229256; called by muse, varscan2
- NUDT5 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as COSV58501956; called by muse, mutect2, varscan2
- NUP88 | c.2203A>G p.I735V | Missense Mutation (SNP) | VAF 81/87 reads (93%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52585147; called by muse, mutect2, varscan2
- OASL | c.756G>C p.E252D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.151); catalogued as COSV57479009; called by muse, mutect2, varscan2
- OR2L3 | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV100742087; called by muse, mutect2
- OR2L8 | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV61727348; called by muse, mutect2, varscan2
- OR2T3 | c.955T>A p.*319Kext*? | Nonstop Mutation (SNP) | VAF 33/146 reads (23%) | catalogued as COSV100613481; called by muse, mutect2, varscan2
- OR51A4 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99062491; called by mutect2, varscan2
- OR51E1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs146565220; called by muse, mutect2, varscan2
- P2RX2 | c.597C>G p.I199M (on ENST00000343948 / NM_170683.4; = p.I127M on NM_012226.5) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57684117; called by muse, mutect2, varscan2
- PAICS | c.495G>C p.M165I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | PolyPhen benign (0.302); catalogued as rs1215185066, COSV51709267; called by muse, mutect2, varscan2
- PBDC1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV64895945; called by muse, mutect2, varscan2
- PCDHA1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs148838866, COSV100974288; called by muse, mutect2, varscan2
- PCDHA12 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV56520545; called by muse, mutect2, varscan2
- PCDHB11 | c.2241G>C p.Q747H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as COSV61311583, COSV61312601; called by muse, mutect2, varscan2
- PCDHGA1 | c.905C>G p.S302* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as rs1285679219, COSV100966123, COSV65297246; called by muse, mutect2, varscan2
- PCDHGB4 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV53968908, COSV99540531; called by muse, mutect2, varscan2
- PDZD8 | c.3376G>C p.D1126H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV53691809; called by muse, mutect2, varscan2
- PEX5 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99871395; called by muse, mutect2, varscan2
- PHACTR2 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1353524540, COSV59856023; called by muse, mutect2, varscan2
- PHACTR2 | c.1612+1G>C p.X538_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as COSV59856032; called by muse, mutect2, varscan2
- PHLPP2 | c.3099G>C p.L1033F | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV62425416; called by muse, mutect2
- PIGV | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV50293895; called by muse, mutect2
- PIK3C2G | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs983678396, COSV56799657, COSV56817034; called by mutect2, varscan2
- PLEC | c.11338G>T p.V3780L (on ENST00000322810 / NM_201380.4; = p.V3670L on NM_000445.5) | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV59656791, COSV59713768; called by muse, mutect2
- PLEKHM1 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69599172; called by muse, mutect2, varscan2
- POLN | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV67026121; called by muse, mutect2, varscan2
- PPP1CA | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV56703907; called by muse, mutect2, varscan2
- PPP2R2B | c.494G>C p.R165P (on ENST00000394409; = p.R231P on NM_181674.2) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV60770132; called by muse, mutect2, varscan2
- PRAMEF2 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 92/537 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.501); catalogued as COSV53577054; called by muse, mutect2, varscan2
- PRKCB | c.1982C>G p.S661C | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57787793; called by muse, mutect2, varscan2
- PROSER1 | c.887C>G p.S296* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100613128; called by muse, mutect2, varscan2
- PRPF39 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.19); catalogued as COSV53532986; called by muse, mutect2, varscan2
- PRRC2A | c.5955C>G p.D1985E | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as COSV52992659; called by muse, mutect2, varscan2
- PRTG | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as rs772194867, COSV66838900; called by muse, mutect2, varscan2
- PSMC2 | c.935G>C p.R312T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV53008118; called by muse, mutect2, varscan2
- PUF60 | c.530A>G p.Y177C (on ENST00000526683 / NM_001362896.2; = p.Y160C on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57589626; called by muse, mutect2, varscan2
- PUS7 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs772351203, COSV62677284; called by muse, mutect2, varscan2
- PWP1 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV69833221; called by muse, mutect2, varscan2
- PXDNL | c.3835C>T p.Q1279* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100687191; called by muse, mutect2, varscan2
- RAB2A | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | catalogued as COSV99390129; called by muse, mutect2, varscan2
- RAB3GAP2 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs189134236, COSV52966414, COSV52967064; called by muse, mutect2, varscan2
- RAD54L2 | c.1195G>T p.V399L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV56579733, COSV56580294; called by muse, mutect2, varscan2
- RANBP2 | c.1213G>C p.D405H | Missense Mutation (SNP) | VAF 76/402 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs750123699, COSV51703644; called by muse, mutect2, varscan2
- RBBP8 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59094124; called by muse, mutect2
- RFX2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.57); catalogued as rs1301547129, COSV57942951; called by muse, mutect2, varscan2
- RIC1 | c.2365C>G p.L789V | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52611693, COSV99316851; called by muse, mutect2, varscan2
- RIMBP2 | c.2861C>G p.T954R | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55477244; called by muse, mutect2
- RNASEL | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV62377294; called by muse, mutect2, varscan2
- RNF166 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV57189487; called by muse, mutect2
- RPGRIP1L | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs778424280, COSV50909806; called by muse, mutect2, varscan2
- S1PR4 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755185881, COSV55739513; called by muse, mutect2, varscan2
- SAMD8 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV65510280; called by muse, mutect2
- SEL1L3 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV99341507; called by muse, mutect2
- SEMA3G | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99203549; called by muse, mutect2, varscan2
- SGO1 | c.1680G>C p.L560F (on ENST00000263753 / NM_001012410.5; = p.L291F on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/141 reads (52%) | PolyPhen benign (0); catalogued as COSV55424325; called by muse, mutect2, varscan2
- SIRT7 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV58711822; called by muse, mutect2, varscan2
- SLC1A3 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs202194656, COSV54313836; called by muse, mutect2, varscan2
- SLC30A6 | c.1237C>G p.L413V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV50873106; called by muse, mutect2, varscan2
- SLC30A9 | c.633A>G p.I211M | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1394953534, COSV52557305; called by muse, mutect2, varscan2
- SLC66A1 | c.443T>A p.L148Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100913222, COSV64321098; called by muse, mutect2, varscan2
- SLITRK5 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV61523992; called by muse, mutect2, varscan2
- SLPI | c.306dup p.N103Qfs*4 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | catalogued as rs745834619; called by mutect2, varscan2
- SMC4 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV58449447; called by muse, mutect2
- SNX17 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52008261; called by muse, mutect2, varscan2
- SOX4 | c.1376C>G p.S459W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55192783; called by muse, mutect2, varscan2
- SP140L | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs867633191, COSV54740893; called by muse, mutect2, varscan2
- SPTAN1 | c.5029-1G>A p.X1677_splice | Splice Site (SNP) | VAF 45/56 reads (80%) | catalogued as COSV63988250; called by muse, mutect2, varscan2
- STAC3 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60414988; called by muse, mutect2, varscan2
- STAP2 | c.591-1G>A p.X197_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | catalogued as rs761279669, COSV55697014; called by muse, mutect2, varscan2
- STS | c.1474C>A p.H492N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99481756; called by muse, mutect2
- SV2B | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100370469, COSV57700676, COSV57701598; called by muse, mutect2, varscan2
- SYPL1 | c.666G>C p.M222I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.294); catalogued as COSV50579120; called by muse, mutect2, varscan2
- TAB2 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV53850980, COSV99644920; called by muse, mutect2, varscan2
- TACC2 | c.7790G>A p.R2597Q (on ENST00000334433; = p.R675Q on NM_006997.4) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1453598568, COSV53284138; called by muse, mutect2, varscan2
- TAF1L | c.62C>G p.S21* | Nonsense Mutation (SNP) | VAF 34/47 reads (72%) | catalogued as COSV99645634; called by muse, mutect2, varscan2
- TCHH | c.5120G>A p.R1707K | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.081); catalogued as rs1413194021, COSV64275985; called by muse, mutect2, varscan2
- TECTA | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as rs139732688; called by muse, mutect2, varscan2
- TENM3 | c.4654G>C p.D1552H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV69312457, COSV69312756; called by muse, mutect2, varscan2
- TGFBR2 | c.1476G>C p.L492F | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55453121, COSV55456184, COSV55460299; called by muse, mutect2, varscan2
- THNSL1 | c.1622C>G p.T541S | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.715); catalogued as rs1050014494, COSV64479542; called by muse, mutect2, varscan2
- TMEM65 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52631053; called by muse, mutect2, varscan2
- TNFRSF19 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.203); catalogued as COSV50315704; called by muse, mutect2, varscan2
- TNN | c.1531G>T p.V511L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as COSV53429644; called by muse, mutect2, varscan2
- TNS1 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.395); catalogued as rs768109006, COSV99412273; called by muse, mutect2
- TRAF3IP2 | c.1509G>T p.Q503H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60676311; called by muse, mutect2, varscan2
- TRMO | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373515403, COSV64293377; called by muse, mutect2, varscan2
- TSC1 | c.2731G>T p.E911* | Nonsense Mutation (SNP) | VAF 123/136 reads (90%) | catalogued as COSV100052746; called by muse, mutect2, varscan2
- TSC22D2 | c.2210C>G p.S737* | Nonsense Mutation (SNP) | VAF 28/120 reads (23%) | catalogued as COSV62622513; called by muse, mutect2, varscan2
- UBR5 | c.5780C>G p.S1927C | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); catalogued as COSV55292343; called by muse, varscan2
- UGT3A2 | c.1489C>A p.L497M | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV56931744; called by muse, mutect2, varscan2
- USF1 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 24/109 reads (22%) | catalogued as COSV99231362; called by muse, mutect2, varscan2
- VCAN | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV54109359; called by muse, mutect2, varscan2
- WAS | c.962G>C p.R321P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs782802310, COSV64997375; called by muse, varscan2
- WDFY3 | c.10085G>T p.G3362V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs1181684998, COSV55706220; called by muse, mutect2, varscan2
- WDR93 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV51533582; called by muse, mutect2
- WIPI2 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV56589832; called by muse, mutect2, varscan2
- WIPI2 | c.1247G>C p.R416T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV99993682; called by muse, mutect2
- XPO4 | c.2612G>T p.G871V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV55009602; called by muse, mutect2
- XPO4 | c.2611G>T p.G871* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99689300; called by muse, mutect2
- ZBTB38 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58542999; called by muse, mutect2, varscan2
- ZC3HC1 | c.1508G>C p.*503Sext*17 | Nonstop Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100316150; called by muse, mutect2, varscan2
- ZFHX3 | c.9006G>C p.K3002N | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51708231, COSV51724609; called by muse, mutect2
- ZKSCAN2 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60157602; called by muse, mutect2, varscan2
- ZNF407 | c.1846C>A p.L616I | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV55259237, COSV55262320; called by muse, mutect2, varscan2
- ZNF407 | c.3079C>T p.H1027Y | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV55259270, COSV99995826; called by muse, mutect2, varscan2
- ZNF44 | c.1105C>G p.L369V (on ENST00000356109 / NM_001164276.2; = p.L321V on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.106); catalogued as COSV61135469; called by muse, mutect2, varscan2
- ZNF514 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54634407; called by muse, mutect2, varscan2
- ZNF514 | c.934G>T p.G312* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV99728093; called by muse, mutect2, varscan2
- ZNF518B | c.757C>G p.Q253E | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV58723361; called by muse, mutect2, varscan2
- ZNF660 | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as rs149936636; called by muse, mutect2, varscan2
- ZNF696 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100350693; called by muse, mutect2
- ZNF713 | c.986A>G p.Y329C (on ENST00000633730 / NM_001366796.2; = p.Y342C on NM_182633.3) | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1450779208, COSV70057032; called by muse, mutect2, varscan2
- ZNF793 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.271); catalogued as COSV71325088; called by muse, mutect2, varscan2
- CDKN1A | c.196dup p.E66Gfs*23 | Frame Shift Ins (INS) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- MYNN | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- TP53 | c.459_477del p.G154Wfs*10 | Frame Shift Del (DEL) | VAF 16/27 reads (59%) | called by mutect2, pindel, varscan2
- AARS2 | c.75C>G p.L25= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99771772; called by muse, mutect2, varscan2
- ADAMTS1 | c.2454A>G p.K818= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV53171468; called by muse, mutect2, varscan2
- ADAMTS20 | c.33C>G p.L11= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV67134447; called by muse, mutect2, varscan2
- AHNAK2 | c.10161C>T p.L3387= | Silent (SNP) | VAF 63/290 reads (22%) | catalogued as rs1210301489, COSV60920810; called by muse, mutect2, varscan2
- ARHGAP39 | c.1788C>T p.P596= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1159900182, COSV99432519; called by muse, mutect2
- C19orf44 | c.534A>G p.Q178= | Silent (SNP) | VAF 43/66 reads (65%) | catalogued as COSV55613024; called by muse, mutect2, varscan2
- CADPS2 | c.2124C>T p.V708= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV57371896; called by muse, mutect2, varscan2
- CCL11 | c.30G>T p.L10= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as COSV59925309; called by muse, mutect2, varscan2
- CDC42BPB | c.4044G>T p.V1348= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1274709312, COSV63473863, COSV63475807; called by muse, mutect2, varscan2
- CWH43 | c.1935C>T p.I645= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV56940696; called by muse, mutect2, varscan2
- CYFIP2 | c.219G>T p.L73= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV59043849; called by muse, mutect2, varscan2
- DNAJA4 | c.6G>A p.V2= (on ENST00000343789; = p.V31= on NM_018602.3) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1429669944, COSV100655269; called by muse, mutect2
- DOP1B | c.2502G>A p.K834= | Silent (SNP) | VAF 61/143 reads (43%) | catalogued as COSV67694115; called by muse, mutect2, varscan2
- DPF1 | c.333C>G p.L111= | Silent (SNP) | VAF 35/179 reads (20%) | catalogued as rs1163465977, COSV62793284; called by muse, mutect2, varscan2
- EPHA1 | c.1542C>T p.V514= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV51972766; called by muse, mutect2, varscan2
- FCGBP | c.6750G>C p.S2250= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- FCGR2C | c.246G>A p.P82= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as rs578080263, COSV100913248; called by muse, mutect2, varscan2
- FCHO1 | c.207G>T p.P69= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs780435067, COSV53183425; called by muse, mutect2, varscan2
- GPR63 | c.879C>T p.L293= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV57742047; called by muse, mutect2, varscan2
- GRIK2 | c.1659C>T p.F553= | Silent (SNP) | VAF 76/172 reads (44%) | catalogued as COSV59749235; called by muse, varscan2
- GRIP2 | c.2115C>A p.A705= (on ENST00000619221; = p.A608= on NM_001080423.4) | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV56122686; called by muse, mutect2, varscan2
- H1-2 | c.540G>C p.A180= | Silent (SNP) | VAF 84/161 reads (52%) | catalogued as COSV59189483, COSV59190009, COSV59190715; called by muse, mutect2, varscan2
- HEATR1 | c.135C>T p.F45= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1277628330, COSV63979429, COSV63979467; called by muse, mutect2, varscan2
- HIVEP2 | c.612G>C p.L204= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV50022836, COSV50077887; called by muse, varscan2
- HS3ST4 | c.963C>T p.L321= | Silent (SNP) | VAF 44/257 reads (17%) | catalogued as rs767372371, COSV58821529; called by muse, mutect2, varscan2
- INAVA | c.903T>G p.L301= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV66257049; called by muse, mutect2, varscan2
- IQGAP1 | c.2679G>T p.R893= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV51587678; called by muse, mutect2, varscan2
- JMJD6 | c.1176C>T p.D392= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs149210415; called by muse, mutect2, varscan2
- KANSL1 | c.2466G>A p.L822= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV52270640; called by muse, mutect2, varscan2
- KRTAP19-5 | c.114C>T p.G38= | Silent (SNP) | VAF 62/180 reads (34%) | catalogued as rs762584510, COSV61859151; called by muse, mutect2, varscan2
- MAP3K13 | c.600G>A p.Q200= | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as COSV53985172, COSV53991704; called by muse, mutect2, varscan2
- MAPKAPK3 | c.348C>T p.I116= | Silent (SNP) | VAF 32/191 reads (17%) | catalogued as COSV63597843; called by muse, mutect2, varscan2
- MESP1 | c.699G>A p.A233= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs781548451, COSV100262392; called by muse, varscan2
- MYCBP2 | c.5529C>G p.L1843= (on ENST00000357337; = p.L1881= on NM_015057.5) | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV62020139, COSV62027528; called by muse, mutect2, varscan2
- MYH3 | c.1809C>T p.N603= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs779289839, COSV56866965; called by muse, mutect2, varscan2
- NDUFA9 | c.513T>C p.N171= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs1359111525, COSV56930287; called by muse, mutect2, varscan2
- NEPRO | c.456C>T p.C152= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs746585371, COSV58723815; called by muse, mutect2, varscan2
- OBSCN | c.13452C>T p.A4484= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs368138638; called by muse, varscan2
- PCDH10 | c.471C>T p.R157= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as COSV52093550; called by muse, mutect2
- PDLIM2 | c.6G>A p.A2= (on ENST00000397760; = p.A252= on NM_021630.6) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1311340770, COSV53553694; called by muse, mutect2, varscan2
- PEX5 | c.687G>T p.L229= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs751973364, COSV56956305; called by muse, mutect2, varscan2
- PLEC | c.12696G>A p.T4232= (on ENST00000322810 / NM_201380.4; = p.T4122= on NM_000445.5) | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as rs200145450, COSV59639795; ClinVar: likely benign; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1227T>C p.D409= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV62612386; called by muse, mutect2, varscan2
- POT1 | c.1401G>A p.S467= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs775385144, COSV62929187; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEH | c.210C>T p.P70= | Silent (SNP) | VAF 134/820 reads (16%) | catalogued as rs1435321432, COSV58884375; called by muse, varscan2
- PRL | c.531C>G p.V177= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs1305147813, COSV60592802; called by muse, mutect2, varscan2
- PSKH2 | c.447C>T p.L149= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1188576412, COSV52609204, COSV52611301, COSV52612348; called by muse, mutect2, varscan2
- RC3H1 | c.1569A>G p.G523= | Silent (SNP) | VAF 56/88 reads (64%) | catalogued as COSV51205171; called by muse, mutect2, varscan2
- RYR1 | c.11412C>T p.L3804= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs376851030; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SETD6 | c.1179T>C p.D393= (on ENST00000219315 / NM_001160305.4; = p.D369= on NM_024860.3) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV54700576; called by muse, mutect2, varscan2
- SLC17A1 | c.978G>C p.L326= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV55080096; called by muse, mutect2, varscan2
- SLC7A5 | c.291C>T p.I97= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs1488736479, COSV55363740; called by muse, mutect2, varscan2
- SMPD2 | c.1197C>T p.A399= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV57806025; called by muse, mutect2, varscan2
- SNCAIP | c.1449C>T p.V483= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV54413772, COSV54414784; called by muse, mutect2
- SPIRE1 | c.738G>A p.K246= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV59158661; called by muse, mutect2, varscan2
- STAB2 | c.7120C>A p.R2374= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs112523896, COSV66342005; called by muse, mutect2, varscan2
- TAF4 | c.2241G>A p.P747= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs780901041, COSV53339658; called by muse, mutect2, varscan2
- TFE3 | c.1200G>A p.Q400= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100252940; called by muse, mutect2
- TFIP11 | c.1056C>G p.L352= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV53225359, COSV53226826; called by muse, mutect2, varscan2
- TIMELESS | c.1950C>G p.L650= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs1333694245, COSV57510573, COSV57513003; called by muse, mutect2, varscan2
- TRERF1 | c.708C>T p.Y236= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV61674289; called by muse, mutect2, varscan2
- TRMO | c.1167G>T p.R389= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV64293371; called by muse, mutect2, varscan2
- TSPAN15 | c.588C>T p.T196= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV64783447; called by muse, mutect2, varscan2
- UNC13A | c.2613C>T p.V871= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs774466433, COSV53200724; called by muse, mutect2, varscan2
- VPS11 | c.618C>T p.L206= (on ENST00000620429; = p.L750= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs782268978, COSV100333633, COSV100333846, COSV100334056; called by muse, mutect2, varscan2
- WAS | c.942G>A p.P314= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs1557007106, COSV64997372; called by muse, varscan2
- ZDHHC11 | c.252C>G p.L84= | Silent (SNP) | VAF 3/9 reads (33%) | called by mutect2, varscan2
- ZNF559 | c.936C>G p.L312= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV57836269; called by muse, mutect2, varscan2
- ZNF600 | c.48C>T p.I16= | Silent (SNP) | VAF 50/318 reads (16%) | catalogued as rs1357076194, COSV57743711; called by muse, mutect2, varscan2
- MIR125B2 | n.27C>A | RNA (SNP) | VAF 11/102 reads (11%) | catalogued as rs1459840793; called by muse, mutect2, varscan2
- MIR125B2 | n.28C>A | RNA (SNP) | VAF 12/104 reads (12%) | catalogued as rs1325186129; called by muse, mutect2, varscan2
- MIR1275 | n.75G>C | RNA (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- PALB2 | c.-1G>T | 5'UTR (SNP) | VAF 6/32 reads (19%) | catalogued as rs1341292125, COSV99848690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TM2D2 | c.228-41G>C | Intron (SNP) | VAF 36/96 reads (38%) | catalogued as COSV65961075; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23174G>A | Intron (SNP) | VAF 23/98 reads (23%) | catalogued as COSV100531344; called by muse, mutect2, varscan2
